Surgical pathology report (de-identified scan), TCGA case TCGA-BP-5007, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BP-5007-01A (Primary Tumor).

[page 1 of 3]
Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

Additional Copy to:

TCGA-BP-5007

Clinical Diagnosis & History:

with left renal mass; Upper pole tumor.

Specimens Submitted:

1: SP: KIDNEY, LEFT, NEPHRECTOMY

2: SP: LYMPH NODES, PARA AORTIC, EXCISION

DIAGNOSIS:

1. SP: KIDNEY, LEFT, NEPHRECTOMY:

Tumor Type:

Renal cell carcinoma - Conventional (clear cell) type
See comment

Fuhrman Nuclear Grade:

Nuclear grade II/IV

Tumor Size:

Greatest diameter is 10.0 cm.

Local Invasion (for renal cortical types):

Not identified

Renal Vein Invasion:

Not identified

Surgical Margins:

Free of tumor

Non-Neoplastic Kidney:

Mild glomerulosclerosis

Adrenal Gland:

Not involved

Lymph Nodes:

Not identified

Staging for renal cell carcinoma/oncocytoma:

pT2 Tumor >7.0 cm in greatest dimension limited to the kidney

Comment: The tumor shows multifocal areas of fibrosis and osseous metaplasia.

2. SP: LYMPH NODES, PARA AORTIC, EXCISION:

Lymph Nodes:

[page 2 of 3]
Not involved
Number of nodes examined:10

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

Gross Description:

1).The specimen is received fresh labeled "left kidney" and consists of a kidney with attached ureter, renal vessels and perinephric fat weighing 725 g in total. The kidney measures 14.5 x 9.0 x 7.8 cm. The attached ureter measures 9.0 cm in length and 0.3 cm in diameter. The attached renal vein measures 0.5 cm in length and 0.4 cm in diameter. The renal vessels and ureter margins are grossly unremarkable. An adrenal gland is identified weighing 12.1 g and measuring 7.5 x 2.5 x 1.5 with a hemorrhagic cortex. The kidney is inked black and bivalved to reveal large multiloculated and calcified golden yellow tan mass measuring 10.0 x 10.0 x 7.0 cm. Sections through the remainder of the kidney reveal a pink brown parenchyma, with a well-defined cortico-medullary junction. The cortex measures 2.8 cm and the calyces appear compressed. No lymph nodes are identified in the perinephric fat. Representative sections are submitted for TPS and for permanent sections. Photographs are taken.

Summary of sections:

UVM -- ureteral and vessel margins
A - adrenal gland
T-- tumor
TSF -- tumor with sinus fat
TK -- tumor with adjacent kidney
RP -- renal pelvis representative sections
K -- representative sections kidney

2). The specimen is received in formalin, labeled "para-aortic lymph nodes" and consists of multiple pink tan firm lymph nodes ranging from 0.5 to 1.2 cm in greatest dimension. All identified lymph nodes are submitted.

Summary of sections:

LN -- lymph nodes
BLN-- bisected lymph nodes

Summary of Sections:

Part 1: SP: KIDNEY, LEFT, NEPHRECTOMY

Block	Sect. Site	PCs
1	a	1
3	add	3
2	k	2
1	rp	1
8	t	8
7	tk	7
1	tsf	1
1	uvm	1

Part 2: SP: LYMPH NODES, PARA AORTIC, EXCISION

[page 3 of 3]
Block	Sect. Site	PCs
3	bln	3
2	ln	2

Source: NCI Genomic Data Commons file e0ef770d-e361-4d28-80f8-4986e0b08341 (TCGA-BP-5007.9CB0B43E-EB83-4F83-A468-EA5E67317420.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).